Somatic mutation profile of tumor specimen MMRF_1910_1_BM_CD138pos (aliquot MMRF_1910_1_BM_CD138pos_T1_KBS5U_L07295) from MMRF case MMRF_1910, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.9 years (22,617 days).
Specimen MMRF_1910_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5d450ea-1df0-46d0-9838-2495336d97dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1910_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1910_1_PB_Whole_C3_KBS5U_L07289; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/272bf416-1026-40cf-ae51-85e856e8ee3c

The open-access MAF lists 130 somatic variants for this specimen: 55 protein-altering or splice-affecting, 13 silent, 62 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, 3'UTR 34, Intron 17, Silent 13, 3'Flank 5, 5'UTR 4, Frame Shift Del 3, Nonsense Mutation 2, RNA 1, 5'Flank 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 14/43 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC099489.1 | c.4697G>T p.R1566L | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.224); catalogued as rs868654713; called by muse, mutect2, varscan2
- ATP6V0E1 | c.14G>A p.G5D | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as COSV54184403; called by muse, mutect2, varscan2
- CYP11A1 | c.1078C>T p.R360W | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.996); catalogued as rs1284060395, CM128312, COSV51432404; called by muse, mutect2, varscan2
- FAM133A | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 107/119 reads (90%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs778761063; called by muse, mutect2, varscan2
- FRMPD2 | c.2350C>T p.R784C | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as rs746192606, COSV59714920; called by muse, mutect2, varscan2
- H2AC17 | c.203G>A p.G68D | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs955073070; called by muse, mutect2, varscan2
- IGSF23 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.794); catalogued as rs918738344, COSV68806887; called by muse, mutect2, varscan2
- MUC16 | c.41601C>A p.D13867E | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.949); catalogued as rs950090539; called by muse, mutect2, varscan2
- MYOCD | c.2086del p.V696Wfs*22 | Frame Shift Del (DEL) | VAF 90/203 reads (44%) | catalogued as COSV100591378; called by mutect2, pindel, varscan2
- OBSCN | c.2335G>A p.V779I | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs765055309, COSV52780215; called by muse, mutect2, varscan2
- OR2J3 | c.43T>C p.F15L | Missense Mutation (SNP) | VAF 9/207 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as rs1562546968; called by muse, mutect2
- OR5D18 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV100450834, COSV61737173; called by muse, mutect2, varscan2
- PLXNA2 | c.3139G>A p.E1047K | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.678); catalogued as rs1213704855; called by muse, mutect2
- PRSS2 | c.682G>A p.V228I | Missense Mutation (SNP) | VAF 50/374 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.62); catalogued as rs1367460773; called by muse, mutect2
- PUM2 | c.2192T>C p.I731T | Missense Mutation (SNP) | VAF 70/130 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as rs902245077; called by muse, mutect2, varscan2
- SEMA3A | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV54862594; called by muse, mutect2, varscan2
- SLC25A41 | c.272C>A p.A91D | Missense Mutation (SNP) | VAF 74/173 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV51196271; called by muse, mutect2, varscan2
- ZNF669 | c.364A>C p.T122P | Missense Mutation (SNP) | VAF 64/199 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs200003972; called by muse, mutect2, varscan2
- ABCA3 | c.490A>C p.M164L | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ANKRD30B | c.3520G>A p.E1174K | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.053); called by mutect2, varscan2
- ATP6V1G1 | c.131T>C p.I44T | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.284); called by muse, varscan2
- C19orf57 | c.1240G>C p.G414R | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.74); called by muse, mutect2
- CNTN3 | c.2240C>A p.T747N | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CPT2 | c.308A>G p.D103G | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CSF2RB | c.2401G>A p.A801T | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DEAF1 | c.103G>A p.G35S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, varscan2
- DIS3 | c.836G>T p.G279V | Missense Mutation (SNP) | VAF 51/59 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNAH5 | c.5665C>A p.L1889M | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.927); called by mutect2, varscan2
- EDC3 | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLOT2 | c.465+2T>A p.X155_splice | Splice Site (SNP) | VAF 62/141 reads (44%) | called by muse, mutect2, varscan2
- FOXB2 | c.290T>C p.F97S | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRIP2 | c.2833G>T p.E945* (on ENST00000619221; = p.E848* on NM_001080423.4) | Nonsense Mutation (SNP) | VAF 27/151 reads (18%) | called by muse, mutect2, varscan2
- IGHV3-33 | c.342C>A p.Y114* | Nonsense Mutation (SNP) | VAF 24/29 reads (83%) | called by mutect2, varscan2
- IQSEC2 | c.2921G>C p.C974S (on ENST00000642864 / NM_001111125.3; = p.C769S on NM_015075.2) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- KIF11 | c.2305A>T p.S769C | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- LAMA3 | c.3093+7T>G | Splice Region (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2, varscan2
- LAMB2 | c.5285A>G p.N1762S | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LVRN | c.2014C>A p.Q672K | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR11A1 | c.756C>G p.F252L | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- PCDHGC3 | c.1267T>A p.Y423N | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POU4F1 | c.1239G>A p.M413I | Missense Mutation (SNP) | VAF 39/46 reads (85%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PRDM10 | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- PRORP | c.963_975del p.S322Gfs*30 | Frame Shift Del (DEL) | VAF 24/53 reads (45%) | called by mutect2, pindel, varscan2
- RBMS1 | c.774_777del p.Y259Tfs*23 | Frame Shift Del (DEL) | VAF 16/113 reads (14%) | called by pindel, varscan2
- SATB2 | c.217C>A p.L73I | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT tolerated (0.98); PolyPhen benign (0.057); called by muse, mutect2
- SHB | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- TEDDM1 | c.670T>C p.Y224H | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- TENM2 | c.4144C>A p.Q1382K (on ENST00000518659 / NM_001122679.2; = p.Q1143K on NM_001080428.3) | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- TENM2 | c.6473G>A p.G2158E (on ENST00000518659 / NM_001122679.2; = p.G1919E on NM_001080428.3) | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- TRBV7-1 | c.214G>T p.D72Y | Missense Mutation (SNP) | VAF 71/191 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- USH2A | c.1372A>T p.T458S | Missense Mutation (SNP) | VAF 112/199 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- WDPCP | c.2176G>T p.D726Y | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZMYND8 | c.881A>T p.K294I (on ENST00000311275 / NM_001363741.2; = p.K314I on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/171 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.344); called by muse, mutect2
- ZNF358 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.46); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- A1BG | c.1074C>A p.L358= | Silent (SNP) | VAF 39/83 reads (47%) | called by muse, mutect2, varscan2
- ADCK5 | c.1389C>T p.F463= | Silent (SNP) | VAF 29/57 reads (51%) | catalogued as rs781885088; called by muse, mutect2, varscan2
- ARHGEF16 | c.468G>A p.A156= | Silent (SNP) | VAF 22/99 reads (22%) | catalogued as rs371783854; called by muse, mutect2, varscan2
- DSC2 | c.912C>T p.I304= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV51865657, COSV99199896; called by muse, mutect2, varscan2
- IGHV2-70 | c.72G>A p.R24= | Silent (SNP) | VAF 62/113 reads (55%) | catalogued as rs571313541; called by muse, varscan2
- IGLV2-11 | c.306G>A p.E102= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as rs552810612; called by muse, mutect2
- IGLV3-10 | c.347G>T p.*116= | Silent (SNP) | VAF 34/35 reads (97%) | called by muse, mutect2, varscan2
- NPTX1 | c.1158G>C p.L386= | Silent (SNP) | VAF 26/33 reads (79%) | catalogued as COSV100151164; called by muse, mutect2, varscan2
- SCUBE2 | c.1413C>T p.F471= | Silent (SNP) | VAF 36/73 reads (49%) | catalogued as rs1448060724; called by muse, mutect2, varscan2
- SH2D2A | c.990C>T p.V330= | Silent (SNP) | VAF 15/189 reads (8%) | called by muse, mutect2
- SMPDL3B | c.1209G>A p.G403= | Silent (SNP) | VAF 59/122 reads (48%) | catalogued as COSV65855181; called by muse, mutect2, varscan2
- UNC5D | c.2829C>T p.A943= | Silent (SNP) | VAF 66/126 reads (52%) | catalogued as rs1197380277, COSV54843057; called by muse, mutect2, varscan2
- ZNF496 | c.630G>A p.V210= | Silent (SNP) | VAF 18/72 reads (25%) | called by muse, mutect2, varscan2
- AC024598.1 | c.981+20296A>G | Intron (SNP) | VAF 41/104 reads (39%) | called by muse, mutect2, varscan2
- ADAM10 | c.2025+93_2025+97del | Intron (DEL) | VAF 44/86 reads (51%) | catalogued as rs370782541; called by mutect2, pindel, varscan2
- APAF1 | c.*2099A>G | 3'UTR (SNP) | VAF 47/95 reads (49%) | called by muse, mutect2, varscan2
- ASB7 | c.*1478G>A | 3'UTR (SNP) | VAF 8/52 reads (15%) | catalogued as rs561358442; called by muse, mutect2, varscan2
- ATP1B4 | c.*1408A>G | 3'UTR (SNP) | VAF 48/50 reads (96%) | called by muse, mutect2, varscan2
- C6orf223 | n.2515G>A | RNA (SNP) | VAF 3/40 reads (8%) | catalogued as rs950175234; called by muse, mutect2
- CCDC91 | chr12:28257140 G>T | 5'Flank (SNP) | VAF 25/130 reads (19%) | called by muse, mutect2, varscan2
- CCER1 | c.*606T>G | 3'UTR (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- CDKL3 | c.*59A>C | 3'UTR (SNP) | VAF 13/92 reads (14%) | called by muse, mutect2, varscan2
- COL1A1 | c.*875A>G | 3'UTR (SNP) | VAF 15/92 reads (16%) | called by muse, mutect2, varscan2
- COL6A6 | c.-14T>A | 5'UTR (SNP) | VAF 60/146 reads (41%) | called by muse, mutect2, varscan2
- COMT | c.615+152G>C | Intron (SNP) | VAF 27/53 reads (51%) | called by muse, mutect2, varscan2
- CSRNP3 | c.*6021G>T | 3'UTR (SNP) | VAF 45/112 reads (40%) | called by muse, mutect2, varscan2
- DGKA | c.2124+112C>A | Intron (SNP) | VAF 25/55 reads (45%) | called by muse, mutect2, varscan2
- DNASE1 | c.*6554A>T | 3'UTR (SNP) | VAF 30/53 reads (57%) | called by muse, mutect2, varscan2
- DSC2 | c.*773T>C | 3'UTR (SNP) | VAF 33/74 reads (45%) | called by muse, varscan2
- EDEM3 | c.*1110A>G | 3'UTR (SNP) | VAF 9/96 reads (9%) | called by muse, mutect2
- ESRP1 | c.490+14C>A | Intron (SNP) | VAF 86/199 reads (43%) | called by muse, mutect2, varscan2
- FYB1 | c.*803T>A | 3'UTR (SNP) | VAF 51/107 reads (48%) | called by muse, mutect2, varscan2
- GCSAML | c.*1999C>A | 3'UTR (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2
- GRIK4 | c.906+5973G>A | Intron (SNP) | VAF 48/83 reads (58%) | catalogued as rs767119773; called by muse, mutect2, varscan2
- GTPBP10 | c.*3482A>T | 3'UTR (SNP) | VAF 41/115 reads (36%) | called by muse, mutect2, varscan2
- H6PD | c.*6146C>A | 3'UTR (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2
- HEATR5A | c.*1508T>A | 3'UTR (SNP) | VAF 37/58 reads (64%) | called by muse, mutect2, varscan2
- HOXD3 | chr2:176173157 G>A | 3'Flank (SNP) | VAF 16/113 reads (14%) | called by muse, mutect2, varscan2
- IGHA1 | c.*15C>T | 3'UTR (SNP) | VAF 14/49 reads (29%) | catalogued as rs1191066111; called by muse, mutect2, varscan2
- JAZF1 | c.*1174A>G | 3'UTR (SNP) | VAF 39/74 reads (53%) | called by muse, mutect2, varscan2
- KMT2A | c.5355-118C>G | Intron (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- LPP | c.*6474del | 3'UTR (DEL) | VAF 10/22 reads (45%) | called by mutect2, varscan2
- LSP1 | c.54-10401C>G | Intron (SNP) | VAF 47/100 reads (47%) | catalogued as rs1250409694; called by muse, mutect2, varscan2
- NDUFB10 | chr16:1965262 C>T | 3'Flank (SNP) | VAF 29/65 reads (45%) | catalogued as rs763444519; called by muse, mutect2, varscan2
- NEMF | c.2466-99A>G | Intron (SNP) | VAF 25/53 reads (47%) | called by muse, mutect2, varscan2
- NKIRAS1 | chr3:23891283 C>G | 3'Flank (SNP) | VAF 24/46 reads (52%) | called by muse, mutect2, varscan2
- PCLO | c.14791+10G>A | Intron (SNP) | VAF 40/79 reads (51%) | catalogued as rs567145523, COSV61656544; called by muse, mutect2, varscan2
- PDCD2 | c.659-1193T>G | Intron (SNP) | VAF 59/110 reads (54%) | called by muse, mutect2, varscan2
- PFDN6 | c.135+13G>A | Intron (SNP) | VAF 19/91 reads (21%) | called by muse, mutect2, varscan2
- PRM2 | c.-95T>C | 5'UTR (SNP) | VAF 24/47 reads (51%) | called by muse, mutect2, varscan2
- PTPRF | c.*994G>C | 3'UTR (SNP) | VAF 30/58 reads (52%) | called by muse, mutect2, varscan2
- PYROXD1 | c.*1064G>T | 3'UTR (SNP) | VAF 8/11 reads (73%) | called by muse, mutect2, varscan2
- RAB21 | c.*1944A>G | 3'UTR (SNP) | VAF 10/99 reads (10%) | called by muse, mutect2
- RBM11 | c.*890A>T | 3'UTR (SNP) | VAF 15/70 reads (21%) | called by muse, mutect2, varscan2
- RNF144B | c.-160C>T | 5'UTR (SNP) | VAF 17/43 reads (40%) | called by muse, mutect2, varscan2
- RNF183 | chr9:113297444 del T | 3'Flank (DEL) | VAF 26/75 reads (35%) | catalogued as rs201943449, COSV99938034; called by mutect2, varscan2
- RPTN | c.*886C>G | 3'UTR (SNP) | VAF 15/102 reads (15%) | called by muse, mutect2, varscan2
- RXFP3 | c.-121C>G | 5'UTR (SNP) | VAF 11/65 reads (17%) | called by muse, mutect2, varscan2
- SH3GL2 | c.*471A>G | 3'UTR (SNP) | VAF 23/109 reads (21%) | called by muse, mutect2, varscan2
- SIM1 | chr6:100386755 G>A | 3'Flank (SNP) | VAF 14/106 reads (13%) | called by muse, mutect2, varscan2
- SLC25A3 | c.157+445C>T | Intron (SNP) | VAF 15/58 reads (26%) | called by muse, mutect2, varscan2
- SLC66A1L | n.443+6521G>A | Intron (SNP) | VAF 25/66 reads (38%) | called by muse, mutect2, varscan2
- SUN3 | c.*169G>A | 3'UTR (SNP) | VAF 29/161 reads (18%) | called by muse, mutect2, varscan2
- TECRL | c.*1530A>T | 3'UTR (SNP) | VAF 24/128 reads (19%) | called by muse, mutect2, varscan2
- TEX261 | c.*1017T>C | 3'UTR (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- TMEM167A | c.*3597T>A | 3'UTR (SNP) | VAF 35/206 reads (17%) | called by muse, mutect2, varscan2
- TMEM213 | c.*1291C>T | 3'UTR (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- TRIB2 | c.564-2952_564-2951insT | Intron (INS) | VAF 25/109 reads (23%) | called by mutect2, pindel*
- TTN | c.10360+3895A>T | Intron (SNP) | VAF 36/91 reads (40%) | called by muse, mutect2, varscan2
- UNC119B | c.*1057C>G | 3'UTR (SNP) | VAF 39/78 reads (50%) | called by muse, mutect2, varscan2
- VSTM5 | c.559+20G>A | Intron (SNP) | VAF 62/123 reads (50%) | called by muse, mutect2, varscan2
- ZEB1 | c.*1020G>A | 3'UTR (SNP) | VAF 32/67 reads (48%) | called by muse, mutect2, varscan2
- ZIC1 | c.*1139A>C | 3'UTR (SNP) | VAF 18/79 reads (23%) | called by muse, mutect2, varscan2
- ZNF280D | c.*852A>G | 3'UTR (SNP) | VAF 18/113 reads (16%) | called by muse, mutect2, varscan2
- ZNF81 | c.*3420T>C | 3'UTR (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
